Somatic mutation profile of tumor specimen MP2PRT-PAPBZW-TMP1-A (aliquot MP2PRT-PAPBZW-TMP1-A-1-0-D-A83M-36) from MP2PRT case MP2PRT-PAPBZW, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: male; Primary diagnosis: Acute lymphoblastic leukemia, NOS; Tissue or organ of origin: Bone marrow; Age at diagnosis: 3.1 years (1,137 days).
Specimen MP2PRT-PAPBZW-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 0803e92c-e0ef-4d80-b7e8-e7f60e88c6fa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAPBZW-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAPBZW-NB1-A-1-0-D-A83M-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/51ace37d-dad4-4fc7-9ea1-7cd0e8c3a1b7

The open-access MAF lists 11 somatic variants for this specimen: 9 protein-altering or splice-affecting, 1 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 8, Intron 1, Silent 1, Splice Region 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- HAPLN3 | c.751C>T p.R251C | Missense Mutation (SNP) | VAF 186/610 reads (30%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.892); catalogued as rs549076731; called by muse, mutect2, varscan2
- PAX5 | c.91C>T p.R31W | Missense Mutation (SNP) | VAF 120/292 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as COSV63905553; called by muse, mutect2, varscan2
- ANKRD20A4P | c.318G>A p.Q106= | Splice Region (SNP) | VAF 4/27 reads (15%) | called by mutect2, varscan2
- KIF12 | c.217G>A p.A73T | Missense Mutation (SNP) | VAF 200/611 reads (33%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.824); called by muse, mutect2, varscan2
- MRPS25 | c.506C>T p.A169V | Missense Mutation (SNP) | VAF 93/270 reads (34%) | SIFT tolerated, low confidence (0.27); PolyPhen benign (0.154); called by muse, mutect2, varscan2
- SLC52A1 | c.461G>A p.S154N | Missense Mutation (SNP) | VAF 135/485 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); called by muse, mutect2, varscan2
- UBN2 | c.1611A>C p.R537S | Missense Mutation (SNP) | VAF 24/264 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.6); called by muse, mutect2
- ZBTB9 | c.517T>A p.S173T | Missense Mutation (SNP) | VAF 184/519 reads (35%) | SIFT tolerated (0.2); PolyPhen benign (0.062); called by muse, mutect2, varscan2
- ZEB2 | c.3215A>G p.Q1072R | Missense Mutation (SNP) | VAF 126/407 reads (31%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); called by muse, mutect2, varscan2
- PCDHA4 | c.1353C>T p.N451= | Silent (SNP) | VAF 178/568 reads (31%) | catalogued as rs782636671, COSV63539191; called by muse, mutect2, varscan2
- SH3TC1 | c.172+301T>G | Intron (SNP) | VAF 112/346 reads (32%) | called by muse, mutect2, varscan2
